Somatic mutation profile of tumor specimen TCGA-ET-A39R-01A (aliquot TCGA-ET-A39R-01A-11D-A19J-08) from TCGA case TCGA-ET-A39R, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 24.2 years (8,828 days).
Specimen TCGA-ET-A39R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44018be3-173f-4ae3-8704-b2cdba7aa3c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A39R-10A (Blood Derived Normal), aliquot TCGA-ET-A39R-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04112208-fe72-4da6-84b7-84f7992c8966

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC100868.1 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs372434452, COSV51839518; called by mutect2, varscan2
- COL5A3 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.829); catalogued as COSV53410208, COSV53416721; called by muse, mutect2, varscan2
- HAUS7 | c.244A>G p.M82V | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV57848993; called by muse, mutect2, varscan2
- ZNF777 | c.1891G>C p.G631R | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV56097484; called by muse, mutect2, varscan2
- IRS1 | c.189G>T p.S63= | Silent (SNP) | VAF 22/193 reads (11%) | catalogued as rs778626516, COSV59336108; called by muse, mutect2, varscan2
